Somatic mutation profile of tumor specimen MP2PRT-PAVNKV-TMP1-A (aliquot MP2PRT-PAVNKV-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVNKV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (718 days).
Specimen MP2PRT-PAVNKV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14ac48d1-864e-4bb6-8a18-cba1c81e1fe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVNKV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVNKV-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2865d40-c338-4c46-8101-2adf3d61e73a

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN12 | c.600G>C p.M200I | Missense Mutation (SNP) | VAF 36/486 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV104410316; called by muse, mutect2
- ZNF619 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs201349894; called by muse, mutect2, varscan2
- ZMYM2 | c.1062_1063del p.F354Lfs*23 | Frame Shift Del (DEL) | VAF 28/203 reads (14%) | called by pindel*, varscan2
- PHEX | c.2106A>G p.R702= | Silent (SNP) | VAF 98/422 reads (23%) | called by muse, mutect2, varscan2
